Somatic mutation profile of tumor specimen TCGA-94-7943-01A (aliquot TCGA-94-7943-01A-11D-2184-08) from TCGA case TCGA-94-7943, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 80.2 years (29,282 days).
Specimen TCGA-94-7943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b97b297-2a66-4488-b72a-fcc81ac457fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-7943-10A (Blood Derived Normal), aliquot TCGA-94-7943-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db44ae14-1259-42f9-8958-b5a4888114b8

The open-access MAF lists 218 somatic variants for this specimen: 152 protein-altering or splice-affecting, 62 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 62, Nonsense Mutation 14, Splice Site 2, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 3'UTR 1, In Frame Del 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 121/158 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.2155G>C p.G719R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as rs1465838742, COSV100598124; called by muse, mutect2
- AHNAK | c.6707G>T p.G2236V | Missense Mutation (SNP) | VAF 82/605 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99950122; called by muse, mutect2, varscan2
- AHNAK | c.3325G>C p.D1109H | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57218360, COSV99950125; called by muse, mutect2
- AHNAK | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV99950128; called by muse, mutect2
- ALPK2 | c.3628A>G p.N1210D | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV100864921; called by muse, mutect2, varscan2
- ANKIB1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56060039, COSV99730082; called by muse, mutect2, varscan2
- ARHGAP36 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99035107, COSV99358323; called by muse, mutect2, varscan2
- ARHGEF2 | c.991G>T p.A331S (on ENST00000361247 / NM_001162383.2; = p.A303S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100561293; called by muse, mutect2, varscan2
- ARHGEF37 | c.1006A>T p.K336* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100382402; called by muse, varscan2
- ARMC8 | c.1625G>A p.R542H (on ENST00000469044 / NM_001363941.2; = p.R528H on NM_015396.6) | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100509939; called by muse, mutect2
- ASH1L | c.6479G>T p.R2160I (on ENST00000368346 / NM_001366177.2; = p.R2155I on NM_018489.3) | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100853631, COSV64209943; called by muse, mutect2, varscan2
- ATM | c.4292A>G p.N1431S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs201356803, COSV99592442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.2695C>G p.R899G | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.033); catalogued as rs137852741, CM002243, COSV101001769; called by muse, mutect2, varscan2
- BRD4 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99651562; called by muse, mutect2, varscan2
- C12orf40 | c.130A>T p.N44Y | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100210902; called by muse, mutect2, varscan2
- C2orf80 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV58016796; called by muse, mutect2
- CAMTA1 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); catalogued as COSV104410476; called by muse, mutect2
- CCDC54 | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53758564, COSV99660345; called by muse, mutect2
- CCDC74B | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100134805; called by muse, mutect2, varscan2
- CCND1 | c.543C>G p.H181Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99919926; called by muse, mutect2
- CDH1 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55738713; called by muse, mutect2, varscan2
- CENATAC | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57722091; called by muse, mutect2, varscan2
- CEP68 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99561369; called by muse, mutect2, varscan2
- CFAP54 | c.5446G>A p.E1816K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV100733423; called by muse, varscan2
- CFHR1 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 135/175 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259044; called by muse, mutect2, varscan2
- CHTF8 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs769216163, COSV54708042, COSV99544854; called by muse, mutect2, varscan2
- CIB1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV100153448; called by muse, mutect2, varscan2
- CLEC16A | c.2881G>C p.D961H | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.062); catalogued as COSV99901818; called by muse, mutect2, varscan2
- COL21A1 | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99056775; called by muse, mutect2
- COMP | c.1554C>A p.D518E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721632; called by muse, mutect2, varscan2
- CSMD3 | c.2192C>T p.T731I (on ENST00000297405 / NM_001363185.1; = p.T627I on NM_052900.3) | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs749445525, COSV99847723, COSV99851161; called by muse, mutect2, varscan2
- CYLD | c.2450G>A p.C817Y | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100282808; called by muse, mutect2, varscan2
- CYP3A5 | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV56120176; called by muse, mutect2, varscan2
- DCAF12L2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as rs776786261, COSV100758920, COSV63581726; called by muse, mutect2
- DDI1 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100161243, COSV56380547; called by muse, varscan2
- DDX23 | c.1265T>A p.I422N | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100340019; called by muse, mutect2, varscan2
- DENND2C | c.2558G>A p.R853H (on ENST00000393274 / NM_001256404.2; = p.R796H on NM_198459.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs1217079690, COSV101283984; called by muse, mutect2, varscan2
- DHRS7C | c.464C>A p.P155H (on ENST00000330255 / NM_001220493.2; = p.P154H on NM_001105571.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1460199706, COSV100364956; called by muse, mutect2, varscan2
- DLG5 | c.4794C>G p.I1598M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100967971; called by muse, mutect2, varscan2
- DNAI2 | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as COSV100210185; called by muse, mutect2, varscan2
- DNAI2 | c.1743_1745del p.E581del | In Frame Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs886053379; called by pindel, varscan2
- DUSP16 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99963438; called by muse, mutect2
- DYRK1B | c.525C>A p.H175Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV100546787; called by muse, mutect2, varscan2
- EDC3 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 24/178 reads (13%) | catalogued as COSV100166017; called by muse, mutect2, varscan2
- ELF3 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100668959, COSV62839131, COSV62839867; called by muse, mutect2, varscan2
- EP400 | c.1909C>T p.Q637* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100202543; called by muse, mutect2, varscan2
- ESYT1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV99920413; called by muse, mutect2, varscan2
- FAM135B | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs781427760, COSV52723858; called by muse, mutect2, varscan2
- FAM187B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61201705; called by muse, mutect2
- FBN2 | c.5813G>T p.C1938F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99331366; called by muse, mutect2, varscan2
- FCN2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99391478; called by muse, mutect2, varscan2
- FOXO1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101092257; called by muse, mutect2, varscan2
- GAL3ST3 | c.659A>C p.D220A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs780045661, COSV61748627, COSV61749042; called by muse, mutect2, varscan2
- GCC2 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV100565601, COSV100565687; called by muse, mutect2, varscan2
- GMIP | c.1674G>C p.R558S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99179672; called by muse, mutect2, varscan2
- GPS1 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100136169; called by muse, mutect2, varscan2
- GRIN2A | c.2390C>A p.T797N | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100411333; called by muse, mutect2, varscan2
- H3C11 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100137751, COSV58899594; called by muse, mutect2, varscan2
- H3C13 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV58943837; called by muse, mutect2, varscan2
- HAUS5 | c.574T>C p.C192R | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99178861; called by muse, mutect2, varscan2
- HHATL | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV100124732; called by muse, mutect2, varscan2
- HIVEP1 | c.7073C>T p.P2358L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.135); catalogued as COSV101045874; called by muse, mutect2, varscan2
- HNRNPA1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as rs61910737, COSV52937419, COSV52938449; called by muse, mutect2, varscan2
- HNRNPA1 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV99267960; called by muse, mutect2, varscan2
- IAPP | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs369714240, COSV99557193, COSV99557221; called by muse, mutect2, varscan2
- INO80B | c.908C>G p.S303* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99270861; called by muse, mutect2, varscan2
- IRS4 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100929815; called by muse, mutect2, varscan2
- IRS4 | c.252C>G p.Y84* | Nonsense Mutation (SNP) | VAF 38/51 reads (75%) | catalogued as COSV100929817; called by muse, mutect2, varscan2
- JAKMIP1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99289262, COSV99291030; called by muse, mutect2, varscan2
- JTB | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 88/232 reads (38%) | catalogued as COSV99665868; called by muse, mutect2, varscan2
- JUP | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60278307; called by muse, mutect2, varscan2
- KALRN | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99567811; called by muse, mutect2, varscan2
- KCNA5 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV52908792; called by muse, mutect2, varscan2
- KCNH6 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs764516818, COSV100121305, COSV59002760; called by muse, mutect2, varscan2
- KNL1 | c.5508G>C p.L1836F (on ENST00000346991 / NM_170589.5; = p.L1810F on NM_144508.5) | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV100707162; called by muse, mutect2, varscan2
- KRTAP19-8 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs200908947, COSV66998473; called by muse, mutect2, varscan2
- LRIG2 | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.138); catalogued as rs1158957915, COSV100743781; called by muse, mutect2, varscan2
- LRP1B | c.10531+1G>T p.X3511_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101262151; called by muse, mutect2, varscan2
- LRP1B | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101262152; called by muse, mutect2, varscan2
- LYST | c.1697T>A p.L566* | Nonsense Mutation (SNP) | VAF 72/201 reads (36%) | catalogued as COSV101090477, COSV67714935; called by muse, mutect2, varscan2
- MAPK15 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100567759, COSV100568161; called by muse, mutect2, varscan2
- MCM6 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV99919458; called by muse, mutect2, varscan2
- ME1 | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63838175; called by muse, mutect2, varscan2
- MED12L | c.6139G>A p.D2047N | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.135); catalogued as rs927774217, COSV56372732, COSV99855123; called by muse, mutect2, varscan2
- MICU3 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100536663; called by muse, mutect2
- MRE11 | c.1061A>T p.N354I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100120166; called by muse, mutect2, varscan2
- MTNR1B | c.421T>A p.Y141N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99925415; called by muse, mutect2, varscan2
- MUC16 | c.43473A>T p.Q14491H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV101110124; called by muse, mutect2, varscan2
- NAA50 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763096981, COSV99568742; called by muse, mutect2, varscan2
- NCAPD2 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV100217140, COSV100217512; called by muse, mutect2, varscan2
- NCOR1 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776976570, COSV51973727; called by muse, mutect2, varscan2
- NLRP13 | c.2136G>A p.M712I | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV61622311; called by muse, mutect2
- OLFML2B | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs541383588, COSV99669051; called by muse, mutect2, varscan2
- OR10G7 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs752771848, COSV100390114; called by muse, mutect2, varscan2
- OR13G1 | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs374414029, COSV100687630; called by muse, mutect2, varscan2
- OR51G1 | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as rs756013017, COSV100429471, COSV58968736; called by muse, mutect2, varscan2
- OR51S1 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437604; called by muse, mutect2, varscan2
- OR5AC2 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62280007; called by muse, mutect2, varscan2
- OR5K4 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100721424; called by muse, mutect2, varscan2
- PAF1 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.31); catalogued as COSV99656105; called by muse, mutect2
- PITPNM1 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.083); catalogued as COSV99653912; called by muse, mutect2, varscan2
- PKHD1 | c.9209A>T p.Q3070L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100584875; called by muse, mutect2
- PLA2G15 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99547468; called by muse, mutect2, varscan2
- PLSCR2 | c.327C>A p.F109L (on ENST00000497985 / NM_001199978.1; = p.F36L on NM_020359.2) | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100367980; called by muse, mutect2, varscan2
- POLQ | c.6241C>T p.Q2081* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as rs752088145, COSV99953167; called by muse, mutect2, varscan2
- PRKD3 | c.1830G>C p.M610I | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99306200, COSV99306899; called by muse, mutect2, varscan2
- PROCR | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV99405854; called by muse, mutect2, varscan2
- PTPN21 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV60849370, COSV60853412; called by muse, mutect2, varscan2
- PUM2 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.281); catalogued as COSV100164084; called by muse, mutect2, varscan2
- RALGAPA1 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99356510; called by muse, varscan2
- REG1B | c.184-2A>T p.X62_splice | Splice Site (SNP) | VAF 56/167 reads (34%) | catalogued as COSV100521555; called by muse, mutect2, varscan2
- RPL27 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV99518577; called by muse, mutect2, varscan2
- SCN1A | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100322568, COSV57674939; called by muse, mutect2, varscan2
- SERPINI1 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99855489; called by muse, mutect2, varscan2
- SH2B2 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs1554557270, COSV100159661, COSV60828064; called by muse, mutect2, varscan2
- SLAMF7 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100833390; called by muse, mutect2, varscan2
- SLC27A1 | c.1536C>G p.F512L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99393790; called by muse, mutect2, varscan2
- SLC6A7 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV100046632; called by muse, mutect2, varscan2
- SNRK | c.1935G>T p.E645D | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV99939480; called by muse, mutect2, varscan2
- SPTY2D1 | c.1556G>C p.G519A | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV100311888; called by muse, mutect2, varscan2
- SRPK2 | c.822G>C p.K274N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100624436; called by muse, mutect2, varscan2
- STAG1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52602826; called by muse, mutect2
- STAT1 | c.-1G>C | Splice Region (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100738938; called by muse, mutect2, varscan2
- SUPT20H | c.1864C>G p.L622V (on ENST00000350612 / NM_001014286.3; = p.L623V on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as rs759705717, COSV100634859; called by muse, mutect2, varscan2
- SYNE1 | c.14410G>T p.V4804L (on ENST00000367255 / NM_182961.4; = p.V4733L on NM_033071.3) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99583509; called by muse, mutect2, varscan2
- TEX12 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99737717; called by muse, mutect2
- TEX12 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV99737719; called by muse, mutect2, varscan2
- TGFB1I1 | c.849C>G p.F283L (on ENST00000394863 / NM_001042454.3; = p.F266L on NM_015927.4) | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs759435542, COSV100691266; called by muse, mutect2, varscan2
- TGIF2LX | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99383567; called by muse, mutect2, varscan2
- TMC2 | c.1251T>G p.S417R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV100728056; called by muse, mutect2, varscan2
- TMEM102 | c.433T>A p.C145S | Missense Mutation (SNP) | VAF 102/117 reads (87%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99548564; called by muse, mutect2, varscan2
- TNPO1 | c.652A>T p.M218L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100474196; called by muse, mutect2, varscan2
- TOX2 | c.151G>T p.G51W (on ENST00000358131 / NM_001098798.2; = p.G42W on NM_001098797.2) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100364858, COSV57890570; called by muse, mutect2, varscan2
- TRAPPC8 | c.2486A>T p.H829L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99352155; called by muse, mutect2, varscan2
- UPF1 | c.2059G>C p.A687P (on ENST00000599848 / NM_001297549.2; = p.A676P on NM_002911.4) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99440575; called by muse, mutect2, varscan2
- USH2A | c.6724G>A p.E2242K | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs375278546, COSV56333969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VARS1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs758503469, COSV65155406; called by muse, mutect2
- ZBTB10 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100990495; called by muse, mutect2, varscan2
- ZNF107 | c.1965G>T p.K655N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV100788568, COSV61327590; called by muse, mutect2, varscan2
- ZNF146 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV61931099, COSV61932451; called by muse, mutect2, varscan2
- ZNF207 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV58301618; called by muse, mutect2, varscan2
- ZNF319 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540524; called by muse, mutect2, varscan2
- ZNF574 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 10/105 reads (10%) | catalogued as COSV99726610; called by muse, mutect2, varscan2
- ZNF585A | c.355C>G p.Q119E (on ENST00000292841 / NM_001288800.2; = p.Q64E on NM_152655.3) | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99493719; called by muse, mutect2, varscan2
- ZNF704 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100589955; called by muse, mutect2, varscan2
- ZNF79 | c.1476G>C p.Q492H | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100688321; called by muse, mutect2
- BHLHE41 | c.166dup p.R56Kfs*6 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- CDC25C | c.403del p.D135Tfs*29 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.235); called by muse, mutect2
- PRR7 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.378); called by mutect2, varscan2
- AMER2 | c.1770C>T p.G590= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV100766417; called by muse, mutect2, varscan2
- AOC1 | c.84G>A p.R28= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV62867192; called by muse, mutect2, varscan2
- AP1G1 | c.102C>T p.I34= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV55490720; called by muse, mutect2, varscan2
- ASF1B | c.417C>T p.I139= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV54615615; called by muse, varscan2
- ASXL2 | c.3270C>T p.F1090= | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as rs774482245, COSV99712246; called by muse, mutect2, varscan2
- C19orf12 | c.132G>A p.L44= (on ENST00000392278 / NM_001031726.3; = p.L33= on NM_031448.6) | Silent (SNP) | VAF 41/206 reads (20%) | catalogued as COSV100080669; called by muse, mutect2, varscan2
- C3orf22 | c.177G>A p.Q59= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV100559563; called by muse, mutect2, varscan2
- CABYR | c.78C>G p.L26= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100510224; called by muse, mutect2, varscan2
- CARM1 | c.1059C>G p.V353= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV99450399; called by muse, mutect2, varscan2
- CCIN | c.1089C>T p.I363= | Silent (SNP) | VAF 63/96 reads (66%) | catalogued as rs147398180; called by muse, mutect2, varscan2
- CCM2 | c.390C>T p.I130= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs1292532913, COSV51847736; called by muse, mutect2, varscan2
- CD163L1 | c.678G>A p.G226= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100550812; called by muse, mutect2, varscan2
- CIART | c.234T>A p.S78= | Silent (SNP) | VAF 47/359 reads (13%) | catalogued as COSV99290461; called by muse, mutect2, varscan2
- CNDP1 | c.123C>T p.Y41= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as rs182983125, COSV100722573; called by muse, mutect2, varscan2
- CSTF1 | c.519G>A p.V173= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV99410390; called by muse, mutect2
- DDX27 | c.1326C>A p.I442= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as COSV100873604; called by muse, mutect2
- DOK5 | c.264C>A p.T88= | Silent (SNP) | VAF 58/217 reads (27%) | catalogued as rs919085564, COSV52826345, COSV99375037; called by muse, mutect2, varscan2
- DPPA4 | c.75G>T p.S25= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs776564280, COSV100169779, COSV59511828; called by muse, mutect2, varscan2
- ELF3 | c.1115G>A p.*372= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100668961, COSV62839698; called by muse, mutect2, varscan2
- EPX | c.582C>T p.F194= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1362845825, COSV99836830; called by muse, mutect2, varscan2
- ERLEC1 | c.1290G>C p.V430= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV99483326; called by muse, mutect2, varscan2
- ESPNL | c.1425G>A p.G475= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1372868504, COSV100547981; called by muse, mutect2, varscan2
- FERMT2 | c.99G>A p.L33= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV100449218; called by muse, mutect2
- GBX1 | c.787C>A p.R263= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV99881173; called by muse, mutect2, varscan2
- GMEB2 | c.438C>T p.I146= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV56606458; called by muse, mutect2
- GPR119 | c.801C>T p.L267= | Silent (SNP) | VAF 64/90 reads (71%) | catalogued as rs144325632, COSV99358741; called by muse, mutect2, varscan2
- HLA-DOA | c.402C>T p.I134= | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as rs965001798, COSV57715035; called by muse, mutect2, varscan2
- HNRNPA1 | c.123G>A p.T41= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs1565879644, COSV52937070; called by muse, mutect2, varscan2
- IFNL3 | c.366C>G p.P122= | Silent (SNP) | VAF 115/227 reads (51%) | catalogued as COSV101308033, COSV69830215; called by muse, mutect2, varscan2
- KBTBD12 | c.306G>A p.Q102= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as COSV100675550; called by muse, mutect2
- KDM2A | c.2985C>T p.L995= | Silent (SNP) | VAF 17/246 reads (7%) | catalogued as COSV100445879; called by muse, mutect2
- LPCAT2 | c.654C>T p.F218= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV50894309; called by muse, mutect2, varscan2
- MAN1A1 | c.885G>A p.L295= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs1222477808, COSV100870451; called by muse, mutect2, varscan2
- MAPKBP1 | c.150T>C p.S50= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV99530332; called by muse, mutect2, varscan2
- MLLT10 | c.2619G>A p.V873= (on ENST00000307729 / NM_001195626.3; = p.V889= on NM_004641.3) | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as COSV100308944; called by muse, mutect2, varscan2
- MRPS28 | c.69C>T p.F23= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52562087; called by muse, mutect2, varscan2
- MYBPC2 | c.426C>T p.D142= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV100732052; called by muse, mutect2, varscan2
- MYH13 | c.5181G>C p.L1727= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99355873; called by muse, mutect2, varscan2
- MYH13 | c.4191G>T p.L1397= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52828835; called by muse, varscan2
- MYL6 | c.357G>A p.K119= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99255309; called by muse, varscan2
- NTM | c.36G>A p.K12= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs938227796, COSV100869848; called by muse, mutect2, varscan2
- NUP85 | c.1353G>A p.L451= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99822408; called by muse, mutect2, varscan2
- OR5AC2 | c.750C>T p.V250= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs368530070, COSV100684538; called by muse, varscan2
- OR5I1 | c.318C>T p.F106= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV56887156; called by muse, mutect2, varscan2
- PDE10A | c.1134G>T p.L378= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100606094; called by muse, mutect2, varscan2
- PITPNC1 | c.945G>C p.L315= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV100084304; called by muse, mutect2, varscan2
- PODXL2 | c.306G>A p.E102= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV61066047; called by muse, mutect2, varscan2
- RNASEK | c.186G>T p.V62= (on ENST00000548577; = p.V23= on NM_001004333.5) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99278569; called by muse, mutect2, varscan2
- RPF1 | c.477C>G p.L159= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101039851, COSV65724643; called by muse, mutect2, varscan2
- SH3BGR | c.66G>A p.V22= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100374650; called by muse, mutect2, varscan2
- SIRT2 | c.756G>A p.L252= | Silent (SNP) | VAF 101/164 reads (62%) | catalogued as COSV50874721; called by muse, mutect2, varscan2
- SLC22A12 | c.234G>A p.P78= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs377022807; called by muse, mutect2, varscan2
- SLC39A4 | c.768C>T p.L256= (on ENST00000301305 / NM_001374839.1; = p.L231= on NM_017767.3) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1437738395, COSV99433882; called by muse, mutect2, varscan2
- STEAP2 | c.789C>A p.A263= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99840732; called by muse, mutect2
- SYNE2 | c.2268T>C p.V756= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100648614; called by muse, mutect2, varscan2
- TOGARAM1 | c.3927T>C p.N1309= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100818307; called by muse, mutect2
- TRRAP | c.11032C>T p.L3678= (on ENST00000359863 / NM_001244580.1; = p.L3649= on NM_003496.3) | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV100705404, COSV100705514; called by muse, mutect2, varscan2
- TRRAP | c.11308C>T p.L3770= (on ENST00000359863 / NM_001244580.1; = p.L3741= on NM_003496.3) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100705357, COSV100705515; called by muse, varscan2
- UCP2 | c.462G>A p.R154= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as COSV100135218; called by muse, mutect2, varscan2
- VPS53 | c.1923C>T p.V641= (on ENST00000571805 / NM_001366253.2; = p.V612= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/57 reads (70%) | catalogued as COSV99346892; called by muse, mutect2, varscan2
- ZNF462 | c.5235C>T p.I1745= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs748308845, COSV52950791; called by muse, mutect2, varscan2
- ZNF792 | c.1197T>C p.C399= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs566122876, COSV68694794; called by muse, mutect2, varscan2
- ACAA2 | chr18:49814085 G>C | 5'Flank (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- ATP11AUN | n.799G>A | RNA (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- SCARF1 | c.*2G>A | 3'UTR (SNP) | VAF 12/335 reads (4%) | catalogued as COSV99557294; called by muse, mutect2
- SRSF6 | c.257-521G>C | Intron (SNP) | VAF 10/122 reads (8%) | catalogued as COSV54827311; called by muse, mutect2
